FM case AD5141 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/1005b03a-1f24-41a1-8511-7f490636e17e

Male, 43.1 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the peritoneum; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
